Surgical pathology report (de-identified scan), TCGA case TCGA-06-0214, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0214-01A (Primary Tumor).

[page 1 of 3]
Name
MRN#:

Sex: male Age: Histology code: MIB: 22% MIB calc:
Histology: GBM

Tissue Bank:

Surgery Date:
Surgeon:
Hospital:
Surg path#:

Additional Data:

AGE/SEX: M DOB:
SURGERY DATE:
RECEIVE DATE:
PHYSICIAN:
COPY TO:

Tissue Amount: 2
Number of Vials: 4
Tissue Loc: L10
Cells cultured:
Consent:

UPDATED REPORT SEE
ADDENDUM REPORT
UPDATED REPORT SEE
SPECIAL STAIN REPORT AND
ADDENDUM DIAGNOSIS.

PATHOLOGICAL DIAGNOSIS:

BRAIN, RIGHT FRONTAL EXCISION:
GLIOBLASTOMA MULTIFORME (SEE
MICROSCOPIC DESCRIPTION AND
COMMENT).

ADDENDUM DIAGNOSIS: BRAIN, MIB-1
LABELING INDEX: 22%.

Operation/Specimen: Tumor right frontal.

[page 2 of 3]
Clinical History and Pre-Op Dx: None provided.

GROSS PATHOLOGY: SITE: tumor right frontal. FIXATIVE: formalin. TYPE: a 4.5 x 3.0 x 2.0 cm. fragment of gray-tan brain tissue, sectioning reveals an ill-defined, approximately 2.0 cm. gray-tan gritty area predominately in the white matter with focal hemorrhage; also scattered petechiae and bordering tissue at the gray-white junction. CASSETTES: 1,2 - tumor; 3 - petechiae and adjacent brain tissue.

MICROSCOPIC: Portions of cerebrum extensively infiltrated by a glial neoplastic proliferation with nuclear features of anaplasia, frequent mitotic figures, and serpiginous areas of tumor necrosis with pseudopalisading. There is a large central area, which is surrounded by vessels with thickened, hyalinized walls and endothelial hyperplasia. Microvascular cellular proliferation is present throughout the neoplasm and in brain tissue being over-run by the infiltrating tumor.

COMMENT: This is a diffusely infiltrating glial neoplasm with cellular anaplasia, microvascular cellular proliferation, mitotic figures and areas of necrosis, namely a glioblastoma multiforme.

ADDENDUM REPORT

SPECIAL STAIN: An immunoperoxidase method for MIB-1 was performed on block 2.

A MIB-1 labeling index of 22% is determined.

Sample Usage:

#1: ~0.1g to

.. ~0.3g to

[page 3 of 3]
, ~0.2g to

~0.2g to

#2:

#3:

#4:

Source: NCI Genomic Data Commons file 8065dcef-97b9-4046-9d8a-273819b7085c (TCGA-06-0214.854F121B-7837-4267-BA58-1392F6E6301B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).